Surgical pathology report (de-identified scan), TCGA case TCGA-EO-A22S, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University Health Network, specimen TCGA-EO-A22S-01A (Primary Tumor).

[page 1 of 4]
1CB-0-3

Adenocarcinoma, endometrioid, NOS 8380/3

Site: Endometrium, NOS C54.1

4/21/11

Surgical Pathology Consultation Report

Gender: F

Specimen(s) Received

1. Uterus: Hysterectomy BSO
2. Lymph node: Right external iliac lymph node
3. Lymph node: Right internal iliac
4. Lymph node: right Obturator
5. Lymph node: Right common iliac
6. Lymph node: Right lower para aortic
7. Lymph node: Left External iliac
8. Lymph node: Left internal iliac
9. Lymph node: Left obturator
10. Lymph node: Left common iliac
11. Lymph node: Lower para aortic

Diagnosis

1. Uterus, left & right fallopian tubes and ovaries:

Uterus:

ADENOCARCINOMA ENDOMETRIUM, ENDOMETRIOID TYPE WITH SQUAMOUS DIFFERENTIATION FIGO GRADE 3/3:

- extension into outer half of myometrial thickness
- lymphovascular space involvement present
- extensive necrosis
- extension into endocervical stroma

Other:

- Leiomyomata uteri

Ovaries:

- Negative for carcinoma

Fallopian tubes:

- Endometriosis left fallopian tube
- Negative for carcinoma

2. Lymph nodes, right external iliac:

[page 2 of 4]
- Negative for carcinoma (six lymph nodes)
- 3. Lymph node, right external iliac:
- Negative for carcinoma (one lymph node)
- 4. Lymph nodes, right obturator:
- Negative for carcinoma (two lymph nodes)
- 5. Lymph nodes, right common iliac:
- Negative for carcinoma (two lymph nodes)
- 6. Lymph nodes, right lower paraaortic:
- Negative for carcinoma (four lymph nodes)
- 7. Lymph nodes, left external iliac:
- Negative for carcinoma (two lymph nodes)
- 8. Lymph nodes, left external iliac:
- Negative for carcinoma (three lymph nodes)
- 9. Lymph nodes, left obturator:
- Negative for carcinoma (three lymph nodes)
- 10. Lymph nodes, left common iliac:
- Negative for carcinoma (two lymph nodes)
- 11. Lymph nodes, lower paraaortic:
- Negative for carcinoma (five lymph nodes)

Synoptic Data

Specimen Type (s):	Total Hysterectomy, Left ovary, Right ovary, Left fallopian tube, Right fallopian tube
Tumor Size:	Greatest dimension: 6.5 cm
Other Organs Present:	Lymph nodes
Histologic Type:	Endometrioid adenocarcinoma, with squamous differentiation
Histologic Grade:	G3: More than 50% nonsquamous solid growth
Myometrial Invasion:	Outer half invasion
Cervix Involvement:	Stromal involvement
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L):	Present
Nodal Involvement:	None
Margins:	Uninvolved by invasive carcinoma
Pathologic Staging (pTNM):	pT1c (IC): Tumor invades one-half or more of the myometrium
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis Number of regional lymph nodes examined: 30 Number of regional lymph nodes involved: 0
Distant Metastasis (pM):	pMX: Distant metastasis cannot be assessed
Additional Pathologic Findings:	None identified

[page 3 of 4]
Electronically

verified by:

Clinical History

endometrial ca

Gross Description

1. The specimen container, labeled with the patient's name and as "Lymph Node: Right iliac external node", contains multiple pieces of fibrofatty tissue measuring 6.5 x 4.8 x 1.5 cm, received in 10% NBF. This contains multiple lymph nodes measuring from 1.0 cm to 3.3 cm. Representative sections are submitted as follows:
1A- one lymph node bisected
1B-1D- one lymph node trisected
1E-1F-multiple lymph nodes each block
1G-1K-fatty tissue.
2. The specimen container, labeled with the patient's name and as "Lymph Node: Right internal iliac node", contains a piece of fibrofatty tissue measuring 4.0 x 2.5 x 0.8 cm, received in 10% NBF. This contains three lymph nodes measuring from 0.7 to 1.7 cm. The specimen is submitted in toto as follows:
2A- two lymph nodes
2B- one lymph node bisected
2C-2D-remainder of fatty tissue.
3. The specimen container, labeled with the patient's name and as "Lymph Node: Right obturator lymph node", contains a piece of fibrofatty tissue measuring 3.2 x 2.3 x 0.8 cm, received in 10% NBF.
3A-3B- specimen is bisected and submitted in toto.
4. The specimen container is labeled with the patient's name and as "Lymph Node: Left external iliac lymph node" consists of two pieces of unoriented fatty tissue measuring 2.2 x 1.2 x 0.7 cm and 3.0 x 3.0 x 2.3 cm received in 10% buffered formalin. Within the fatty tissue, multiple lymph nodes are identified measuring from 0.7 to 2.7 cm. The specimen is submitted in toto as follows:
4A- multiple lymph nodes
4B- two lymph nodes
4C-4D- one lymph node bisected
4E-4G-remainder of fatty tissue.
5. The specimen container is labeled with the patient's name and as "Lymph Node: Left internal iliac lymph node" consists of a single piece of unoriented fatty tissue measuring 2.1 x 1.2 received in 10% buffered formalin.
5A specimen is bisected and submitted in toto.
6. The specimen container is labeled with the patient's name and as "Lymph Node: Left obturator lymph node" consists of four fragments of unoriented fatty tissue measuring from 0.9 x 0.6 x 0.3 cm to 2.5 x 1.4 x 0.8 cm received in 10% buffered formalin.
6A-6D- submitted in toto.
7. The specimen container is labeled with the patient's name and as "Uterus: Uterus, tubes and ovaries" consists of a uterine corpus with attached cervix, bilateral tubes and ovaries weighing 172.3 g received in 10% buffered formalin. The uterus and cervix measures 9.5 cm SI x 6.7 cm

[page 4 of 4]
ML x 4.0 cm AP while the cervix measures 2.8 cm in diameter with a slit shaped os measuring 0.8 cm. The right ovary measures 2.4 x 1.2 x 0.7 cm with a solid yellow-tan appearance on cut surface while the right fallopian tube is fimbriated and measures 5.4 cm in length and 0.8 cm in diameter and is otherwise unremarkable. The left ovary measures 2.1 x 1.2 x 0.6 cm with a solid gray-tan appearance on cut surface while the left fallopian tube is fimbriated and measures 4.2 cm in length and 0.6 cm in diameter with multiple paratubal cysts measuring up to 0.7 cm. The endo cervical and exocervical mucosa are congested but otherwise unremarkable. The uterine serosa is congested with fibrous adhesions. There is a fungating tan-brown friable tumor mass on the anterior and posterior endometrium extending from the upper to the mid lower portion predominantly on the left side measuring 4.8 cm SI x 4.2 cm ML with a depth of 0.4 cm. Grossly, the tumor appears to be superficial but approaches into the myometrium. The myometrium is trabeculated and slightly thickened and contains multiple well-circumscribed nodules measuring from 0.3 to 0.8 cm. These nodules are solid in consistency with a whorled appearance on cut surface. Representative sections are submitted as follows:

7A- left fallopian tube, left ovary previously submitted by the research assistant

7B- right fallopian tube, right ovary previously submitted by the research assistant

7C- endometrial tumor previously submitted by the research assistant.

7D-7E-remainder of right ovary submitted in toto.

7F-7H-remainder of right fallopian tube and fimbriae submitted in toto.

7I-7J-remainder of left ovary submitted in toto.

7K-7M-remainder of left fallopian tube and fimbriae submitted in toto.

7N-7Q-two full transverse sections of the anterior upper endomyometrium.

7R-7U-longitudinal section of the anterior endomyometrium from mid upper to lower including the cervix.

7V-7Y-two full transverse sections of the posterior upper endomyometrium

7Z-7AC-longitudinal section of the posterior endomyometrium from mid upper to lower including the cervix.

7AD-endometrial tumor.

Multiple pieces were taken for tissue bank.

Source: NCI Genomic Data Commons file 2b611d3a-4f47-4887-8c4e-4b1a33eb2997 (TCGA-EO-A22S.DB26485C-BE5C-4874-B79D-7FCFFFF70C4E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).